Somatic mutation profile of tumor specimen TCGA-IW-A3M5-01A (aliquot TCGA-IW-A3M5-01A-22D-A21Q-09) from TCGA case TCGA-IW-A3M5, project TCGA-SARC (Sarcoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Leiomyosarcoma, NOS; Tissue or organ of origin: Uterus, NOS; Age at diagnosis: 76.3 years (27,869 days).
Specimen TCGA-IW-A3M5-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) cb7a2306-6bf9-4b1c-9595-2abf0a9bb29e.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-IW-A3M5-10A (Blood Derived Normal), aliquot TCGA-IW-A3M5-10A-01D-A21Q-09; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/1a6a7127-9332-44f9-924c-c197f0811fa9

The open-access MAF lists 49 somatic variants for this specimen: 33 protein-altering or splice-affecting, 15 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 27, Silent 15, Frame Shift Del 4, Splice Region 2, 3'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- KRAS | c.183A>T p.Q61H | Missense Mutation (SNP) | VAF 34/54 reads (63%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen benign (0.121); catalogued as rs17851045, COSV55498802, COSV55499223, COSV55811221; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- PIK3CA | c.3140A>G p.H1047R | Missense Mutation (SNP) | VAF 42/43 reads (98%) | hotspot (GDC flag); SIFT tolerated (0.11); PolyPhen benign (0.085); catalogued as rs121913279, CM153086, COSV55873195, COSV55873401, COSV55888015; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2
- PPP2R1A | c.536C>G p.P179R | Missense Mutation (SNP) | VAF 33/67 reads (49%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as rs786205228, CM153573, COSV59042232, COSV59042841; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- TP53 | c.614A>G p.Y205C | Missense Mutation (SNP) | VAF 37/49 reads (76%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1057520007, COSV52665440, COSV52677268, COSV52688506; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- CHD2 | c.637G>C p.D213H | Missense Mutation (SNP) | VAF 72/96 reads (75%) | SIFT deleterious (0.04); PolyPhen benign (0.224); catalogued as COSV59121749; called by muse, mutect2, varscan2
- COL13A1 | c.607C>T p.P203S (on ENST00000398978 / NM_001130103.2; = p.P165S on NM_080798.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 8/82 reads (10%) | SIFT tolerated (0.27); PolyPhen probably damaging (0.995); catalogued as COSV100637794; called by muse, mutect2, varscan2
- ECT2 | c.335C>T p.S112L (on ENST00000392692 / NM_001349098.2; = p.S81L on NM_018098.6 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 24/122 reads (20%) | SIFT tolerated (0.07); PolyPhen benign (0.071); catalogued as COSV99222207; called by muse, varscan2
- INTS4 | c.1808T>A p.I603N | Missense Mutation (SNP) | VAF 17/82 reads (21%) | SIFT tolerated (0.53); PolyPhen benign (0.023); catalogued as COSV101417276; called by muse, mutect2, varscan2
- KCNC2 | c.1088G>A p.R363H | Missense Mutation (SNP) | VAF 5/13 reads (38%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs550561919, COSV54373814; called by muse, mutect2, varscan2
- LAMA5 | c.8995G>A p.V2999M | Missense Mutation (SNP) | VAF 29/62 reads (47%) | SIFT deleterious (0.03); PolyPhen benign (0.379); catalogued as rs776263026; called by muse, mutect2, varscan2
- LTBP1 | c.4539C>T p.N1513= (on ENST00000404816 / NM_206943.4; = p.N1187= on NM_000627.4) | Splice Region (SNP) | VAF 28/78 reads (36%) | catalogued as rs762533656; called by muse, mutect2, varscan2
- NKAPL | c.125G>A p.R42H | Missense Mutation (SNP) | VAF 30/55 reads (55%) | SIFT tolerated (0.23); PolyPhen benign (0); catalogued as rs1445644216; called by muse, mutect2, varscan2
- OR8G5 | c.535T>G p.C179G | Missense Mutation (SNP) | VAF 43/51 reads (84%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); catalogued as COSV100422220; called by muse, mutect2, varscan2
- PLEKHA4 | c.892C>T p.R298C | Missense Mutation (SNP) | VAF 15/36 reads (42%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.65); catalogued as rs765995329, COSV54361056; called by muse, mutect2, varscan2
- RAD54L2 | c.1007C>T p.P336L | Missense Mutation (SNP) | VAF 22/26 reads (85%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1403859230, COSV56578410; called by muse, mutect2, varscan2
- ZNF777 | c.107G>T p.R36L | Missense Mutation (SNP) | VAF 7/8 reads (88%) | SIFT tolerated, low confidence (0.23); PolyPhen benign (0.018); catalogued as rs374336310; called by muse, mutect2, varscan2
- ADGRB3 | c.274C>G p.H92D | Missense Mutation (SNP) | VAF 6/33 reads (18%) | SIFT tolerated (0.38); PolyPhen possibly damaging (0.888); called by muse, mutect2, varscan2
- AMY2B | c.460G>T p.G154C | Missense Mutation (SNP) | VAF 71/282 reads (25%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.767); called by muse, mutect2, varscan2
- ANKRD12 | c.2370G>T p.M790I | Missense Mutation (SNP) | VAF 10/18 reads (56%) | SIFT tolerated, low confidence (0.57); PolyPhen benign (0); called by muse, varscan2
- CCDC62 | c.1705del p.S569Vfs*3 | Frame Shift Del (DEL) | VAF 7/55 reads (13%) | called by mutect2, pindel, varscan2
- CUL7 | c.4486_4489del p.D1496Cfs*71 | Frame Shift Del (DEL) | VAF 10/23 reads (43%) | called by mutect2, varscan2
- DCLK1 | c.926C>A p.A309D | Missense Mutation (SNP) | VAF 15/46 reads (33%) | SIFT tolerated (0.27); PolyPhen benign (0.197); called by muse, mutect2, varscan2
- GIN1 | c.400C>T p.L134F | Missense Mutation (SNP) | VAF 5/43 reads (12%) | SIFT deleterious (0.02); PolyPhen benign (0.3); called by muse, mutect2
- ILVBL | c.80C>G p.A27G | Missense Mutation (SNP) | VAF 6/27 reads (22%) | SIFT tolerated, low confidence (0.19); PolyPhen benign (0); called by mutect2, varscan2
- IQCD | c.151A>G p.R51G | Missense Mutation (SNP) | VAF 52/262 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- MAP3K9 | c.2219A>G p.K740R (on ENST00000554752 / NM_001284230.1; = p.K754R on NM_033141.4) | Missense Mutation (SNP) | VAF 16/41 reads (39%) | SIFT tolerated (0.3); PolyPhen benign (0.017); called by muse, mutect2, varscan2
- MMS22L | c.2563A>C p.K855Q | Missense Mutation (SNP) | VAF 27/59 reads (46%) | SIFT deleterious (0.01); PolyPhen benign (0.014); called by muse, mutect2
- OLA1 | c.501_513del p.E168* | Frame Shift Del (DEL) | VAF 12/54 reads (22%) | called by mutect2, pindel, varscan2
- PKHD1L1 | c.8352C>G p.N2784K | Missense Mutation (SNP) | VAF 40/92 reads (43%) | SIFT deleterious (0); PolyPhen possibly damaging (0.616); called by muse, mutect2, varscan2
- RGL1 | c.1576T>C p.S526P (on ENST00000360851 / NM_001297672.2; = p.S561P on NM_015149.5 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 8/59 reads (14%) | SIFT tolerated (0.09); PolyPhen benign (0); called by muse, mutect2, varscan2
- SHPRH | c.1073A>G p.E358G | Missense Mutation (SNP) | VAF 21/42 reads (50%) | SIFT deleterious (0); PolyPhen possibly damaging (0.665); called by muse, mutect2, varscan2
- SRPX | c.719_720del p.T240Sfs*3 | Frame Shift Del (DEL) | VAF 26/48 reads (54%) | called by pindel, varscan2
- TTC37 | c.993A>G p.Q331= | Splice Region (SNP) | VAF 18/28 reads (64%) | called by muse, mutect2, varscan2
- ABCC11 | c.2022G>A p.E674= | Silent (SNP) | VAF 10/77 reads (13%) | catalogued as rs756605321; called by muse, mutect2, varscan2
- ACTRT1 | c.630C>T p.A210= | Silent (SNP) | VAF 49/68 reads (72%) | catalogued as rs962032863, COSV100947517, COSV100947582; called by muse, mutect2, varscan2
- CPT2 | c.214T>C p.L72= | Silent (SNP) | VAF 88/135 reads (65%) | catalogued as rs1468795324; called by muse, mutect2, varscan2
- ECT2 | c.411C>T p.V137= (on ENST00000392692 / NM_001349098.2; = p.V106= on NM_018098.6 and 2 other RefSeq transcripts) | Silent (SNP) | VAF 30/115 reads (26%) | called by muse, varscan2
- ESPNL | c.2859C>T p.H953= | Silent (SNP) | VAF 8/17 reads (47%) | catalogued as rs750687420, COSV58036269; called by muse, mutect2, varscan2
- FAM83A | c.837G>A p.V279= | Silent (SNP) | VAF 8/69 reads (12%) | catalogued as COSV99414614; called by muse, mutect2, varscan2
- GDF10 | c.477C>A p.G159= | Silent (SNP) | VAF 14/14 reads (100%) | called by muse, mutect2, varscan2
- KAT6B | c.1551C>G p.P517= | Silent (SNP) | VAF 51/75 reads (68%) | called by muse, mutect2, varscan2
- LSS | c.897C>T p.L299= | Silent (SNP) | VAF 19/32 reads (59%) | catalogued as rs777414371; called by muse, mutect2, varscan2
- MYBBP1A | c.2571G>T p.R857= | Silent (SNP) | VAF 16/20 reads (80%) | called by muse, mutect2, varscan2
- NOM1 | c.870A>G p.E290= | Silent (SNP) | VAF 22/27 reads (81%) | called by muse, mutect2, varscan2
- PTPN21 | c.1384C>T p.L462= | Silent (SNP) | VAF 20/48 reads (42%) | called by muse, mutect2, varscan2
- TENT5A | c.447C>T p.R149= | Silent (SNP) | VAF 47/99 reads (47%) | called by muse, mutect2, varscan2
- YIPF7 | c.675A>T p.S225= | Silent (SNP) | VAF 14/17 reads (82%) | called by muse, mutect2
- ZFHX4 | c.7581G>A p.P2527= | Silent (SNP) | VAF 15/29 reads (52%) | catalogued as rs373464374, COSV50496365; called by muse, mutect2, varscan2
- ZNF99 | c.*690G>A | 3'UTR (SNP) | VAF 34/72 reads (47%) | catalogued as rs191061145, COSV101234007; called by muse, mutect2, varscan2
